Somatic mutation profile of tumor specimen MMRF_2611_1_BM_CD138pos (aliquot MMRF_2611_1_BM_CD138pos_T1_KHS5U_L12929) from MMRF case MMRF_2611, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,430 days).
Specimen MMRF_2611_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44f2c06f-537e-421d-bd40-b8873deac55d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2611_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2611_1_PB_Whole_C3_KHS5U_L12897; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23670af3-5546-4951-ac0c-4b1558158468

The open-access MAF lists 152 somatic variants for this specimen: 51 protein-altering or splice-affecting, 19 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 38, Intron 28, Silent 19, 5'UTR 6, 5'Flank 5, Nonsense Mutation 4, 3'Flank 3, RNA 2, Splice Region 2, Frame Shift Del 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.736A>C p.M246L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 166/183 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV67132116; called by muse, mutect2, varscan2
- CHD3 | c.5384G>A p.R1795Q (on ENST00000330494 / NM_001005273.3; = p.R1761Q on NM_005852.4) | Missense Mutation (SNP) | VAF 84/91 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1487730047; called by muse, mutect2, varscan2
- CLCC1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 24/284 reads (8%) | catalogued as COSV56765888; called by muse, mutect2
- DNAH5 | c.7559C>T p.P2520L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1234844527; called by muse, mutect2, varscan2
- FCRLA | c.711G>C p.R237S (on ENST00000367959; = p.R214S on NM_032738.4) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as rs1197981223; called by muse, mutect2, varscan2
- IRF2BP2 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64015724; called by muse, varscan2
- KANK3 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as rs576440651; called by muse, mutect2, varscan2
- LRRFIP2 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.842); catalogued as rs1157640430; called by muse, mutect2, varscan2
- ODF3L2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774779124, COSV52746048; called by muse, mutect2, varscan2
- PNMA1 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 106/119 reads (89%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54095701; called by muse, mutect2, varscan2
- RASA2 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 17/293 reads (6%) | catalogued as COSV53939795; called by muse, mutect2
- REEP2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 195/367 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.314); catalogued as rs772821081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16B | c.2987G>T p.G996V | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs772826191; called by muse, mutect2
- TFAP2B | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 89/99 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs939682057, COSV53829960; called by muse, mutect2, varscan2
- ZMIZ2 | c.166-3T>C | Splice Region (SNP) | VAF 22/134 reads (16%) | catalogued as rs752121402; called by muse, mutect2, varscan2
- ZNF835 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs867181808, COSV73379145; called by muse, mutect2
- AATK | c.3303_3305dup p.L1103dup (on ENST00000326724 / NM_001080395.3; = p.L1000dup on NM_004920.2) | In Frame Ins (INS) | VAF 95/108 reads (88%) | called by mutect2, pindel, varscan2
- ABCB9 | c.1958T>A p.M653K (on ENST00000280560 / NM_019625.4; = p.M610K on NM_019624.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- ATG2B | c.5911C>T p.P1971S | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT tolerated (0.74); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BCO1 | c.334T>G p.Y112D | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- BSPRY | c.785G>C p.C262S | Missense Mutation (SNP) | VAF 203/391 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CACNA1B | c.6077C>T p.A2026V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CALM3 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CDKN2C | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 95/109 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT4 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- CTNNAL1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- DDR2 | c.2027C>G p.S676C | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DIPK1A | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- EHD1 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 209/473 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FATE1 | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FOXO1 | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAN | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- GRM8 | c.885A>C p.K295N | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- IGLV1-47 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 67/72 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ILK | c.727A>C p.R243= | Splice Region (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- INTS5 | c.266_285del p.L89Pfs*36 | Frame Shift Del (DEL) | VAF 182/368 reads (49%) | called by pindel, varscan2*
- KIF3B | c.997T>C p.Y333H | Missense Mutation (SNP) | VAF 124/126 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNL1 | c.2491G>T p.V831F (on ENST00000346991 / NM_170589.5; = p.V805F on NM_144508.5) | Missense Mutation (SNP) | VAF 379/415 reads (91%) | SIFT tolerated (0.32); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- NDN | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NFKB2 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NTN1 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR1E | c.715G>T p.D239Y (on ENST00000377792 / NM_001282766.1; = p.D177Y on NM_022490.4) | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RMDN3 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- RRBP1 | c.3224_3225del p.S1075Cfs*54 (on ENST00000377813 / NM_001365613.2; = p.S642Cfs*54 on NM_004587.3) | Frame Shift Del (DEL) | VAF 283/462 reads (61%) | called by pindel, varscan2
- SORCS1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SOX6 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 183/427 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMOD4 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- USP53 | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- ZDHHC17 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- ZNF292 | c.252T>G p.S84R | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ANKRD18B | c.864G>A p.L288= | Silent (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- ARAP3 | c.1230G>T p.V410= | Silent (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- DEF8 | c.129A>T p.T43= | Silent (SNP) | VAF 66/80 reads (83%) | called by muse, mutect2, varscan2
- EPHA6 | c.3306T>C p.L1102= | Silent (SNP) | VAF 134/326 reads (41%) | called by muse, varscan2
- EVI5L | c.2067C>T p.I689= | Silent (SNP) | VAF 11/234 reads (5%) | catalogued as rs1403735328; called by muse, mutect2
- GAREM1 | c.2052C>T p.V684= (on ENST00000269209 / NM_001242409.2; = p.V683= on NM_022751.3) | Silent (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- MEX3B | c.1230C>T p.V410= | Silent (SNP) | VAF 21/316 reads (7%) | catalogued as rs1240528269; called by muse, mutect2
- MSH6 | c.2670C>T p.V890= | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- MUC6 | c.492G>A p.V164= | Silent (SNP) | VAF 6/157 reads (4%) | catalogued as rs1321251924; called by muse, mutect2
- NPSR1 | c.411C>T p.Y137= | Silent (SNP) | VAF 65/120 reads (54%) | catalogued as rs372990147; called by muse, mutect2, varscan2
- NPY2R | c.699C>T p.G233= | Silent (SNP) | VAF 89/97 reads (92%) | catalogued as COSV61528852, COSV61529484; called by muse, mutect2, varscan2
- PDE9A | c.1116G>A p.A372= | Silent (SNP) | VAF 214/230 reads (93%) | catalogued as rs760638698; called by muse, mutect2, varscan2
- PNN | c.51G>A p.E17= | Silent (SNP) | VAF 73/78 reads (94%) | catalogued as rs143676445, COSV53767397; called by muse, mutect2, varscan2
- SHANK1 | c.3384C>G p.P1128= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- SLC2A13 | c.351G>A p.A117= | Silent (SNP) | VAF 65/71 reads (92%) | called by muse, mutect2, varscan2
- UBR5 | c.4285C>T p.L1429= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- WASF3 | c.1344T>A p.I448= | Silent (SNP) | VAF 81/85 reads (95%) | called by muse, mutect2, varscan2
- ZBTB21 | c.87G>A p.L29= | Silent (SNP) | VAF 65/334 reads (19%) | catalogued as rs1176894363; called by muse, mutect2, varscan2
- ZNF506 | c.543T>C p.T181= | Silent (SNP) | VAF 32/278 reads (12%) | called by muse, mutect2, varscan2
- AAGAB | c.535+4903T>G | Intron (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- AC011487.2 | n.908A>G | RNA (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- ACBD3 | c.*1256G>A | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- ACOT11 | c.*1032T>C | 3'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as rs1264017790; called by muse, mutect2
- ADAM33 | c.906-9C>T | Intron (SNP) | VAF 26/28 reads (93%) | catalogued as COSV100598085; called by muse, mutect2, varscan2
- AFF4 | c.*114C>T | 3'UTR (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- AIFM1 | c.249+1196G>A | Intron (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- APLF | c.*38T>A | 3'UTR (SNP) | VAF 13/342 reads (4%) | catalogued as rs1440142617; called by muse, mutect2
- CABLES2 | c.*811C>G | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- CCDC115 | chr2:130342627 C>A | 5'Flank (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- CCDC141 | c.1899+2751A>T | Intron (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- CENPS | chr1:10430067 C>T | 5'Flank (SNP) | VAF 47/51 reads (92%) | catalogued as rs1275533395; called by muse, mutect2
- CEP164 | c.3749-22C>A | Intron (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2
- CEPT1 | c.487+12T>A | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- CHP2 | c.67+86G>A | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- FAM214B | c.*586C>G | 3'UTR (SNP) | VAF 119/246 reads (48%) | called by muse, mutect2, varscan2
- FBN1 | c.164+147C>A | Intron (SNP) | VAF 17/297 reads (6%) | called by muse, mutect2
- FOXP2 | c.1267-1479T>C | Intron (SNP) | VAF 33/335 reads (10%) | catalogued as rs1051708993; called by muse, mutect2
- GAL3ST4 | c.-188-49C>A | Intron (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- GDI1 | c.*306dup | 3'UTR (INS) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
- GET4 | c.317-210G>A | Intron (SNP) | VAF 71/155 reads (46%) | catalogued as rs772742103; called by muse, mutect2, varscan2
- GMPPB | chr3:49717470 C>T | 3'Flank (SNP) | VAF 76/149 reads (51%) | called by muse, mutect2, varscan2
- GPR146 | c.*681G>T | 3'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- GRPEL2 | c.*2348G>A | 3'UTR (SNP) | VAF 8/117 reads (7%) | catalogued as rs1397003922; called by muse, mutect2
- HS2ST1 | c.*384C>T | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- HSD3BP2 | n.209G>A | RNA (SNP) | VAF 83/87 reads (95%) | catalogued as rs778369927; called by muse, mutect2, varscan2
- IQCE | c.1969+142C>T | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as rs761071554; called by muse, varscan2
- JPH3 | c.*725G>A | 3'UTR (SNP) | VAF 183/204 reads (90%) | catalogued as rs1007172120; called by muse, mutect2, varscan2
- KPNA5 | c.*45+173T>A | Intron (SNP) | VAF 42/42 reads (100%) | called by muse, varscan2
- KRBOX1 | c.-47+804G>A | Intron (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- KRTAP22-1 | c.-6G>A | 5'UTR (SNP) | VAF 15/461 reads (3%) | called by muse, mutect2
- LEPROTL1 | c.*324G>T | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- MAML2 | c.*1375C>A | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- MAP3K5 | c.-34G>A | 5'UTR (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- MEGF9 | c.*2429C>A | 3'UTR (SNP) | VAF 14/97 reads (14%) | catalogued as rs574508999; called by muse, mutect2, varscan2
- METTL3 | c.-60T>C | 5'UTR (SNP) | VAF 179/194 reads (92%) | called by muse, mutect2, varscan2
- MGAT5 | c.*5068C>A | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- MS4A4A | c.42-2124A>T | Intron (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- NADK2 | c.*631A>G | 3'UTR (SNP) | VAF 6/170 reads (4%) | called by muse, mutect2
- NCAM2 | c.*1909_*1910del | 3'UTR (DEL) | VAF 14/55 reads (25%) | catalogued as rs1211629255; called by mutect2, pindel, varscan2
- NCOR2 | c.*859G>T | 3'UTR (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- NEPRO | c.474-37C>G | Intron (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- NEPRO | c.474-38A>T | Intron (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- NR1I2 | c.*279C>T | 3'UTR (SNP) | VAF 89/168 reads (53%) | called by muse, mutect2, varscan2
- OSMR | c.*1029del | 3'UTR (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- PAX6 | c.11-859A>T | Intron (SNP) | VAF 172/352 reads (49%) | called by muse, mutect2, varscan2
- PDGFA | c.580+215C>T | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs539789716; called by muse, mutect2
- PGF | c.76-10C>T | Intron (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- PIP4P2 | c.*1175del | 3'UTR (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- PKLR | c.*163C>T | 3'UTR (SNP) | VAF 38/65 reads (58%) | catalogued as rs774442850; called by muse, mutect2, varscan2
- PLD3 | c.678+142C>T | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- POF1B | c.*902A>T | 3'UTR (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- PPP1R21 | c.*291A>T | 3'UTR (SNP) | VAF 34/37 reads (92%) | called by muse, mutect2, varscan2
- PPP4R3B | c.-278C>G | 5'UTR (SNP) | VAF 14/410 reads (3%) | called by muse, mutect2
- PTPRD | c.*1189G>T | 3'UTR (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- RASAL1 | chr12:113099109 del TGATTCT | 3'Flank (DEL) | VAF 68/86 reads (79%) | called by mutect2, pindel, varscan2
- RPL4 | c.*71A>T | 3'UTR (SNP) | VAF 51/95 reads (54%) | catalogued as rs1436773850; called by muse, mutect2, varscan2
- RPL7A | c.3+13T>C | Intron (SNP) | VAF 273/597 reads (46%) | catalogued as rs782010887; called by muse, mutect2, varscan2
- RRAS2 | c.*315G>T | 3'UTR (SNP) | VAF 40/472 reads (8%) | called by muse, mutect2
- SGMS2 | chr4:107914966 T>C | 3'Flank (SNP) | VAF 44/48 reads (92%) | called by muse, mutect2, varscan2
- SIX4 | c.*2766G>A | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- SMCO1 | c.*372G>A | 3'UTR (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- SNTB1 | c.*256G>A | 3'UTR (SNP) | VAF 92/98 reads (94%) | catalogued as rs1192033551; called by muse, mutect2, varscan2
- SPAG6 | c.*773A>G | 3'UTR (SNP) | VAF 52/83 reads (63%) | called by muse, mutect2, varscan2
- SPIN1 | c.*1214G>C | 3'UTR (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- SPINT1 | c.1115-56C>T | Intron (SNP) | VAF 15/280 reads (5%) | called by muse, mutect2
- SPRED1 | c.-181G>C | 5'UTR (SNP) | VAF 52/141 reads (37%) | called by muse, mutect2, varscan2
- THSD7B | c.140-65508G>T | Intron (SNP) | VAF 135/143 reads (94%) | called by muse, mutect2, varscan2
- TMED3 | c.*618G>A | 3'UTR (SNP) | VAF 76/131 reads (58%) | catalogued as rs959533039; called by muse, mutect2, varscan2
- TMEM14B | c.293+348A>T | Intron (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- TMEM185B | c.*452A>C | 3'UTR (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- TMSB4X | chrX:12975304 G>A | 5'Flank (SNP) | VAF 144/165 reads (87%) | catalogued as COSV66081281; called by muse, mutect2, varscan2
- TRAPPC9 | c.2811-22839A>G | Intron (SNP) | VAF 160/172 reads (93%) | called by muse, mutect2, varscan2
- TRIP11 | c.*112T>A | 3'UTR (SNP) | VAF 56/58 reads (97%) | called by muse, mutect2, varscan2
- TROAP | c.2099-84C>T | Intron (SNP) | VAF 66/116 reads (57%) | called by muse, varscan2
- UBE2NL | c.*614G>C | 3'UTR (SNP) | VAF 10/352 reads (3%) | called by muse, mutect2
- USP32 | c.1136+2669C>T | Intron (SNP) | VAF 82/92 reads (89%) | called by muse, mutect2, varscan2
- UTF1 | c.*46G>A | 3'UTR (SNP) | VAF 38/44 reads (86%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-1562del | 5'UTR (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- ZMAT3 | c.*3663T>A | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- ZNF516 | chr18:76496361 C>T | 5'Flank (SNP) | VAF 93/163 reads (57%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280808 C>G | 5'Flank (SNP) | VAF 94/102 reads (92%) | called by muse, mutect2, varscan2
